CCDI case PBCRNW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/32630975-e340-407a-b5e4-93c47d5e49a6

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ganglioneuroblastoma: ICD-O-3 morphology code: 9490/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 10.5 years (3,831 days).

Biospecimens (2 samples)
- Sample 0DXMLO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DXMNF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
